Gene-level copy-number profile of specimen HCM-CSHL-0180-C25-85B from HCMI case HCM-CSHL-0180-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.0 years (23,371 days).
Specimen HCM-CSHL-0180-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 717cc951-2691-49aa-9c22-cbdbba7f018a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0180-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/7bfbe57d-e6ad-47fb-8a2d-ab8dfd6cfbaa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 11,325; copy number 2: 46,738; copy number 3: 267; copy number 6: 52.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:8,603,547–8,680,934, 2 genes: RPSAP68, CR381572.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 52 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:18,638,861–19,417,276, 52 genes, copy number 6: AC026271.4, AC026271.1, ZNF286B, FOXO3B, UBE2SP2, TRIM16L, AC026271.3, FBXW10, TVP23B, AC107982.3, AC107982.1, PRPSAP2, RN7SL627P, AC107982.2, AC090286.3, AC090286.2, SLC5A10, AC090286.1, FAM83G, AC090286.4, GRAP, AC003957.1, SNORD3B-1, SNORD3B-2, AC007952.3, KYNUP2, AC007952.7, AC007952.2, AC007952.4, SNORD3D, SNORD3D, GRAPL, AC007952.6, AC007952.9, AC007952.1, AC007952.5, AC007952.8, KYNUP1, SNORD3A, SNORD3C, AC106017.1, KYNUP3, EPN2, AC106017.2, EPN2-AS1, B9D1, MIR1180, AC124066.1, MAPK7, MFAP4, RNF112, AC004448.3.

Autosomal genes at a single copy (total copy number 1): 9,275. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
